Surgical pathology report (de-identified scan), TCGA case TCGA-DU-A5TP, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Henry Ford Hospital, specimen TCGA-DU-A5TP-01A (Primary Tumor).

[page 1 of 3]
Surgical Pathology Report

Patient Name: Phone #: Accession #:
Med. Rec. #: Client: Taken:
DOB: Location: Received:
Gender: M Acct: Reported:
Physician(s):
Phy Location:

Clinical History

Right parietal tumor

Operative Diagnoses

Operation / Specimen

A: Brain tumor, biopsy

B: Brain tumor, excision biopsy

Pathologic Diagnosis

A. and B. Brain, right parietal tumor, biopsy and excision: Anaplastic astrocytoma, WHO grade III (see comment).

Comment

Permanent sections confirm the frozen section diagnosis. Sections show a moderately pleomorphic infiltrating glioma with mostly angular and irregular hyperchromatic nuclei. Some rounder nuclei are also present perhaps suggesting a minor oligodendroglial component. Mitotic activity is increased in areas of high cellular density (slide A2). The Ki-67 labeling index is approximately 10% overall but focally approaches approximately 45%. An experimental antibody for the R132H IDH1 mutation is positive. Controls show appropriate reactivity. Results of additional studies will be reported below in procedure addenda.
Electronically Signed Out

Senior Staff Pathologist

Procedures/Addenda

PCR for EGFR variant III mutation

Date Ordered: Date Reported:

Interpretation

NEGATIVE - No evidence of EGFRvIII mutation is detected

Surgical Pathology

Results-Comments

TEST DESCRIPTION: Testing performed on RNA extracted from paraffin tissue block H and E slide was examined and no microdissection was needed. The epidermal growth factor receptor (EGFR) is an attractive molecular target in glioblastoma because it is amplified, overexpressed, and/or mutated in up to 40% to 50% of patients. Epidermal growth factor receptor variant III (EGFRvIII) is an oncogenic, constitutively active mutant form of EGFR that is commonly expressed in glioblastoma. Cell culture and in vivo models of glioblastoma have demonstrated EGFRvIII as defining prognostically distinct subgroups of glioblastomas. Additionally, the presence of EGFRvIII has been shown to sensitize tumors to EGFR

66CF ICD-O-3
Astrocytoma, grade III 940113
path Astrocytoma, anaplastic 940113
Site 66CF Supratentorial NOS C71.0
path Brain, parietal lobe C71.3
Op 4/18/13

UUID: CD515DSF-80C5-4571-B431-6091CA4B4848

[page 2 of 3]
tyrosine kinase inhibitors when the tumor suppressor protein PTEN is intact. RNA is extracted from formalin fixed, paraffin embedded tissue samples and reverse transcribed to cDNA. The cDNA is then amplified using standard PCR technique for DNA templates. PCR products are detected by gel electrophoresis. The limit of detection of this assay has been determined to be approximately 5 mutant cells in 100 normal cells.
FDA Comment: The above data are not to be construed as the results from a stand alone diagnostic test. This test was developed and its performance characteristics determined by the as required by CLIA '88 regulations. It has not been cleared or approved for specific uses by the U.S. Food and Drug Administration (FDA). The FDA has determined that such clearance or approval is not necessary. These results are provided for informational purposes only, and should be interpreted only in the context of established procedures and/or diagnostic criteria.
Electronically Signed Out

Senior Staff Pathologist

Loss of Heterozygosity 1p, 19q Assay (LOH)

Date Ordered: **Date Reported:**

Interpretation

POSITIVE: Allelic loss on chromosome arm 19q is detected.

NEGATIVE: Allelic loss on chromosome arm 1p is NOT detected.

Informative loci are: D1S1592, D1S1612, D1S496, D19S219, D19S412

Results-Comments

Testing performed on DNA extracted from tumor paraffin block
corresponding blood specimen was used as a normal reference control.

DNA extracted from a

H and E slide was examined and no microdissection was needed.

TEST DESCRIPTION: Allelic loss is assessed by PCR assay in Normal DNA (baseline)/ Tumor DNA pairs using 3

markers at both 1p and 19q. The 3 markers on 1p are D1S548, D1S1592, and D1S552 (with D1S468, D1S1612, and

D1S496 as backup markers) and the 3 markers on 19q are D19S219, D19S412, and PLA2G4C (with D19S606 and

D19S1182 as backup). All markers are microsatellites (2 or 4 nt repeats) except PLA2G4C which is a minisatellite (26

nt repeat) polymorphism. The markers were selected based on heterozygosity score, amplicon size, and ease of

interpretation. The backup markers are used if the first line markers at that chromosome arm are uninformative or

otherwise ambiguous in their interpretation. LOH at all informative loci on each chromosomal arm represents the

typical finding in oligodendrogliomas with 1p and 19q deletion.

FDA COMMENT: The above data are not to be construed as the results from a stand-alone diagnostic test. This test

was developed and its performance characteristics determined by the as required

Surgical Pathology

by CLIA ' 88 regulations. It has not been cleared or approved for specific uses by the U.S. Food and Drug Administration (FDA). The FDA has determined that such clearance or approval is not necessary. These results are

provided for informational purposes only, and should be interpreted only in the context of established procedures

and/or diagnostic criteria.

[page 3 of 3]
TECHNICAL SENSITIVITY: The presence of >15% non-neoplastic cells in the sample may preclude the detection of allelic loss.

Electronically Signed Out

Senior Staff Pathologist

MGMT Promoter Methylation

Date Ordered: Date Reported:

Interpretation

NEGATIVE: No evidence of methylated MGMT promoter is detected.

Results-Comments

Testing performed on DNA extracted from tumor paraffin block

H and E slide was examined and no microdissection was needed.

TEST DESCRIPTION: Patients with glioma containing a methylated MGMT promoter have been shown to benefit

from therapy with alkylating agents. Assessment of MGMT promoter methylation status involves bisulfite treatment of

DNA followed by real-time PCR amplification of methylated and unmethylated DNA sequences. The

analytic sensitivity of this assay was determined by serial dilution of methylated positive control DNA into unmethylated DNA, and was assessed to be 1% of methylated DNA in the background of unmethylated DNA. Factors

such as the presence of >50% non-neoplastic cells in the sample, or extensive tissue necrosis, may preclude the

detection of methylated MGMT promoter sequences.

FDA COMMENT: The above data are not to be construed as the results from a stand alone diagnostic test. This test

was developed and its performance characteristics determined by the as required

by CLIA '88 regulations. It has not been cleared or approved for specific uses by the U.S. Food and Drug Administration (FDA). The FDA has determined that such clearance or approval is not necessary. These results are

provided for informational purposes only, and should be interpreted only in the context of established procedures

and/or diagnostic criteria.

Electronically Signed Out

Senior Staff Pathologist

Intra-Operative Consultation

A. Brain tumor, biopsy: High-grade glioma. Frozen section and smears performed at and results

reported to the Physician of Record.

Senior Staff Pathologist

Gross Description

A. Brain tumor, biopsy:

CONTAINER LABEL: FS brain tumor.

FIXATIVE: Formalin. NO. PIECES: no info given from frozen. SIZE/VOL: # mm. CASSETTES: 1, 2- cassettes

transferred as received, NS,

Surgical Pathology

Dual/Syn.chronous Primary Noted		

Source: NCI Genomic Data Commons file 58b45bf3-a7fc-4fe7-b8e2-31c27bdfad0b (TCGA-DU-A5TP.CD515D5F-80C5-4571-B431-6091CA4B4848.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).